FM case AD502 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary.
https://portal.gdc.cancer.gov/cases/ff49d5a2-4e65-45e5-a6c8-53e88a2a1f2c

Female, 35.1 years: Serous carcinoma, NOS (ICD-O-3 8441/3) of the ovary; specimen biopsied or resected from the unknown primary site. Tumor nuclei on the sequenced sample's slide: 60% (pathologist estimate recorded by GDC). Sample type: Tumor.
